Gene-level copy-number profile of tumor specimen TCGA-BR-8077-01A from TCGA case TCGA-BR-8077, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.6 years (21,413 days).
Specimen TCGA-BR-8077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.b315d9ad-9c8b-443d-90ab-5ac6c9de5e7a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8077-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63074865-537f-4e32-b33b-4aedd0514b78

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 12; copy number 2: 3,159; copy number 3: 9,834; copy number 4: 21,089; copy number 5: 12,064; copy number 6: 3,263; copy number 7: 3,001; copy number 8: 1,741; copy number 9: 1,689; copy number 10: 415; copy number 11: 855; copy number 12: 126; copy number 13: 1,336; copy number 14: 754; copy number 15: 54; copy number 16: 207; copy number 17: 16; copy number 19: 9; copy number 20: 67; copy number 24: 5; copy number 27: 18; copy number 34: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8077-01A-11D-2338-01): tumor purity 0.6, ploidy 4.8, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–52,866,835, 24 genes: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B.
- chr4:52,945,649–52,958,087, 1 gene: AC023154.1.
- chr8:25,841,725–26,867,278, 15 genes (within-gene range 0–2): EBF2, RNA5SP258, AC079097.1, PPP2R2A, SDAD1P1, BNIP3L, AC011726.1, DNAJB6P2, AC011726.2, PNMA2, DPYSL2, PSME2P5, ADRA1A, AC091675.1, COX6B1P4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5,531 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:104,853,285–105,438,513, 15 genes, copy number 10: AC018730.1, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1.
- chr2:136,199,114–139,511,555, 29 genes, copy number 9–11: HNRNPKP2, AC112255.1, UBBP1, RN7SKP141, SMC4P1, THSD7B, RNA5SP105, Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72.
- chr2:202,032,770–202,205,188, 8 genes, copy number 9: AC069148.1, FZD7, KIAA2012, KIAA2012-AS1, AC079354.2, AC079354.1, PSMA2P3, DAZAP2P1.
- chr4:201,409–2,462,942, 84 genes, copy number 10 (broad region; genes not listed).
- chr4:2,463,797–2,464,124, 1 gene, copy number 10: AL645924.1.
- chr5:2,921,496–45,895,970, 625 genes, copy number 9–17 (broad region; genes not listed).
- chr7:12,469,621–32,428,131, 329 genes, copy number 9–24 (within-gene range 7–24) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,533 genes, copy number 9–16 (broad region; genes not listed).
- chr11:5,170,351–5,229,395, 7 genes, copy number 11: OR51A1P, OR52Z1, OR51V1, AC104389.2, AC104389.7, AC104389.1, HBB.
- chr12:49,861,207–72,186,618, 696 genes, copy number 9–14 (broad region; genes not listed).
- chr12:72,249,964–72,276,954, 1 gene, copy number 9: TRHDE-AS1.
- chr15:53,419,865–53,762,878, 3 genes, copy number 9 (within-gene range 2–9): AC066614.1, WDR72, RNU2-53P.
- chr15:87,859,751–95,826,499, 200 genes, copy number 9–17 (broad region; genes not listed).
- chr15:96,045,341–96,084,584, 2 genes, copy number 9: AC024337.1, AC024337.2.
- chr15:97,572,185–100,919,391, 76 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr17:41,123,091–41,930,542, 63 genes, copy number 34 (within-gene range 3–34) (broad region; genes not listed).
- chr17:69,355,133–71,871,750, 24 genes, copy number 9: AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1.
- chr18:47,390–3,025,566, 70 genes, copy number 9–12 (broad region; genes not listed).
- chr18:20,946,906–22,933,764, 44 genes, copy number 11 (within-gene range 8–11): ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2.
- chr18:22,882,825–22,900,995, 2 genes, copy number 11: AC090912.3, UBE2CP2.
- chr18:30,989,365–31,760,880, 21 genes, copy number 12: DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52.
- chr20:87,250–31,723,989, 602 genes, copy number 13–27 (broad region; genes not listed).
- chr20:38,378,825–61,940,617, 496 genes, copy number 9–16 (within-gene range 6–16) (broad region; genes not listed).
- chr22:15,290,718–26,383,597, 600 genes, copy number 9–13 (within-gene range 7–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
